Gene-level copy-number profile of tumor specimen TCGA-02-0016-01A from TCGA case TCGA-02-0016, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,271 days).
Specimen TCGA-02-0016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b31838fe-3dbc-48d4-a984-47453ba2bef6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0016-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b24b2db-a4aa-4bee-a531-8dc3b0e267f1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1; copy number 2: 10,143; copy number 3: 24; copy number 4: 43,398; copy number 5: 1,713; copy number 6: 4,455; copy number 12: 7; copy number 26: 29; copy number 33: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0016-01): tumor purity 0.83, ploidy 1.95, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 72 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,318,861, 7 genes, copy number 12 (within-gene range 6–12): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:54,759,348–55,211,628, 4 genes, copy number 33 (within-gene range 6–33): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr7:128,455,840–128,493,859, 1 gene, copy number 33 (within-gene range 6–33): AC010655.4.
- chr7:128,476,729–128,914,063, 31 genes, copy number 33: METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1, CALU, RN7SL81P, OPN1SW, CCDC136, FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB, AC025594.1.
- chr19:4,127,492–4,535,224, 29 genes, copy number 26 (within-gene range 5–26): Metazoa_SRP, CREB3L3, SIRT6, ANKRD24, EBI3, AC005578.1, YJU2, SHD, TMIGD2, FSD1, STAP2, AC104521.1, MPND, AC007292.3, EIF1P6, AC007292.2, SH3GL1, AC007292.1, CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2, PLIN4, PLIN5.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
